Gene-level copy-number profile of tumor specimen TCGA-G2-A2EK-01A from TCGA case TCGA-G2-A2EK, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 57.5 years (20,995 days).
Specimen TCGA-G2-A2EK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.d5a5ecc2-2387-4258-9d33-726fa1a37508.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G2-A2EK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e8e8d7a3-5ee7-47e4-94e0-12cb3e8f1190

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 1; copy number 2: 8,021; copy number 3: 1; copy number 4: 45,187; copy number 5: 430; copy number 6: 4,530; copy number 7: 5; copy number 8: 199; copy number 9: 1,384; copy number 10: 2; copy number 81: 41.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G2-A2EK-01A-22D-A18E-01): tumor purity 0.54, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:65,687,301–65,688,468, 1 gene: ILF2P1.
- chr8:33,604,856–34,039,104, 1 gene (within-gene range 0–2): AF279873.3.
- chr8:33,859,480–35,093,509, 10 genes: AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1.
- chr8:35,254,344–35,256,605, 1 gene: AC090740.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,427 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:51,257,688–51,321,118, 1 gene, copy number 10: AC012413.1.
- chr8:51,435,602–51,436,509, 1 gene, copy number 10: BRIX1P1.
- chr8:54,509,422–54,871,720, 1 gene, copy number 9 (within-gene range 5–9): RP1.
- chr8:54,696,398–55,081,909, 2 genes, copy number 9: AC090151.1, AC084834.1.
- chr8:55,135,203–55,164,727, 2 genes, copy number 9: AC022679.2, AC022679.1.
- chr8:56,160,909–145,066,685, 1,379 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr12:68,610,855–69,959,097, 40 genes, copy number 81: RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL.
- chr12:69,946,543–69,947,081, 1 gene, copy number 81: AC078922.1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
